Somatic mutation profile of tumor specimen TCGA-61-2000-01A (aliquot TCGA-61-2000-01A-01W-0722-08) from TCGA case TCGA-61-2000, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.7 years (24,723 days).
Specimen TCGA-61-2000-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00bb8a4e-836e-42fd-a05a-82896158dd59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2000-11A (Solid Tissue Normal), aliquot TCGA-61-2000-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/838384e3-2004-46f5-acb8-10d48ff21ca8

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 16, Nonsense Mutation 2, Splice Site 1, Translation Start Site 1, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 33/37 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747342068, CM086989, CM973641, COSV52689323, COSV52708494, COSV52979406, COSV53353999; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AP1G1 | c.319A>C p.I107L | Missense Mutation (SNP) | VAF 75/136 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV55485068; called by muse, mutect2, varscan2
- AP3S2 | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV60517395; called by muse, mutect2, varscan2
- APOB | c.3089T>G p.V1030G | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51922206; called by muse, mutect2, varscan2
- BRINP3 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66512599; called by muse, mutect2, varscan2
- CA14 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 159/269 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199642489; called by muse, mutect2, varscan2
- CDK8 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV67419074; called by muse, mutect2, varscan2
- CMPK1 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64101626; called by muse, mutect2, varscan2
- CSF1R | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV53828010, COSV53841972; called by muse, mutect2, varscan2
- CUL9 | c.4514A>G p.Y1505C | Missense Mutation (SNP) | VAF 147/304 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs991106724, COSV99334494; called by muse, mutect2, varscan2
- FAM222A | c.621C>G p.N207K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV62722869; called by muse, mutect2, varscan2
- FLNA | c.2576C>A p.T859N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.288); catalogued as COSV100774190; called by mutect2, varscan2
- FMNL3 | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.789); catalogued as rs559972863, COSV53297599; called by muse, mutect2, varscan2
- GAB3 | c.1428T>A p.S476R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV65818751; called by muse, mutect2, varscan2
- GGPS1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 44/145 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV51396852; called by muse, mutect2, varscan2
- GRIA2 | c.1130A>T p.E377V | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV52381621; called by muse, mutect2, varscan2
- KRTAP19-4 | c.242T>A p.L81* | Nonsense Mutation (SNP) | VAF 104/126 reads (83%) | catalogued as COSV61858104; called by muse, varscan2
- MAP1S | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs1344140113, COSV60721495; called by muse, mutect2, varscan2
- MYH11 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567285465, COSV55542203; called by muse, mutect2, varscan2
- MYO3A | c.419A>T p.H140L | Missense Mutation (SNP) | VAF 262/374 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56318866; called by muse, mutect2, varscan2
- MYO5B | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201966606, COSV53210640; called by muse, mutect2
- OR2M2 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 249/697 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100677127; called by mutect2, varscan2
- OR2M5 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs927025517, COSV100822691, COSV63546584; called by muse, mutect2
- PLB1 | c.1471A>G p.M491V | Missense Mutation (SNP) | VAF 164/277 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV59818978; called by muse, mutect2, varscan2
- PON2 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs868720971, COSV99749227; called by muse, mutect2
- RASGRP3 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1208098851, COSV67820295; called by muse, mutect2, varscan2
- RASSF2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV101040531; called by muse, mutect2
- RCBTB1 | c.1211A>C p.N404T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV51633123; called by muse, mutect2, varscan2
- RPS24 | c.113C>G p.T38R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV62602155; called by muse, mutect2, varscan2
- SH2D2A | c.568-2A>T p.X190_splice | Splice Site (SNP) | VAF 149/692 reads (22%) | catalogued as COSV100948994; called by muse, mutect2, varscan2
- SLC6A7 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371591379, COSV100045856; called by muse, mutect2, varscan2
- TMOD4 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 41/1193 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV99765797; called by muse, mutect2
- TRPC7 | c.783C>T p.N261= | Splice Region (SNP) | VAF 25/53 reads (47%) | catalogued as rs774965806, COSV61452376; called by muse, mutect2, varscan2
- UGT2A1 | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 67/445 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs151326445, COSV54137868, COSV99684575; called by muse, mutect2, varscan2
- UNC13C | c.1341G>C p.Q447H | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99509572; called by muse, varscan2
- VSIG4 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191123524, COSV66073073; called by muse, mutect2, varscan2
- WDCP | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54592910; called by muse, mutect2
- ZNF799 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 19/666 reads (3%) | catalogued as COSV101345218; called by muse, mutect2
- CDK12 | c.263_281del p.A88Gfs*30 | Frame Shift Del (DEL) | VAF 16/28 reads (57%) | called by mutect2, varscan2
- BACH2 | c.234G>A p.L78= | Silent (SNP) | VAF 15/262 reads (6%) | catalogued as COSV99997596; called by muse, mutect2
- CEACAM6 | c.364C>T p.L122= | Silent (SNP) | VAF 38/874 reads (4%) | catalogued as COSV99555352; called by muse, mutect2
- DBF4 | c.1395C>G p.S465= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV55995777, COSV55996273; called by muse, varscan2
- DNAH11 | c.10011C>T p.I3337= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV60938360; called by muse, mutect2, varscan2
- FLG2 | c.5640C>T p.H1880= | Silent (SNP) | VAF 30/584 reads (5%) | catalogued as COSV101165524; called by muse, mutect2
- FNDC7 | c.1839C>A p.T613= | Silent (SNP) | VAF 128/279 reads (46%) | catalogued as COSV54750520; called by muse, mutect2, varscan2
- GUCY1B1 | c.1236G>A p.V412= | Silent (SNP) | VAF 98/176 reads (56%) | catalogued as COSV52373480; called by muse, mutect2, varscan2
- OR10AG1 | c.168T>C p.N56= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs1433001137, COSV56631258; called by muse, mutect2, varscan2
- P2RY10 | c.147T>A p.L49= | Silent (SNP) | VAF 286/806 reads (35%) | catalogued as COSV50680317; called by muse, varscan2
- PBDC1 | c.165A>T p.S55= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV64895550; called by muse, mutect2, varscan2
- PCK1 | c.993C>A p.G331= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV100099805; called by muse, mutect2
- SLCO2B1 | c.510G>C p.S170= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV56932821; called by muse, varscan2
- STAT6 | c.33C>T p.P11= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV55668864; called by muse, mutect2, varscan2
- THBS2 | c.432G>A p.L144= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as COSV64676963; called by muse, mutect2, varscan2
- TTN | c.20106T>C p.T6702= (on ENST00000591111; = p.T5775= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100588182; called by muse, mutect2, varscan2
- ZNF7 | c.1476T>G p.T492= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- SNORD116-27 | n.70A>G | RNA (SNP) | VAF 13/224 reads (6%) | called by muse, mutect2
